Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5185, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5185-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

TCGA - BP - 5185

Specimens Submitted:

1: SP: Kidney, right, partial nephrectomy

2: SP: Kidney, right, biopsy

DIAGNOSIS:

1. SP: Kidney, right, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.3 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. Kidney, right, biopsy:

The tissue is submitted to our medical kidney consultant at NYPH/Cornell for processing and interpretation. A supplementary report will follow.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation and is labeled "right renal mass stitch marks deep surgical margin". It consists of a 6.0 x 5.5 x 4.0 cm wedge shaped portion of kidney with perirenal fat and a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a 3.3 x 3.2 x 3.0 cm lobulated, orange yellow, well defined, predominantly solid tumor with hemorrhage and necrosis. The tumor focally abuts the deep margin. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

TS- tumor to sinus

Summary of Sections:

Part 1: SP: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	m	1
1	rs	1
5	t	5
4	ts	4

Part 2: SP: Kidney, right, biopsy

Procedures/Addenda:

Addendum

Status: Signed Out

By:

Addendum Diagnosis

DIAGNOSIS:

THE SPECIMEN WAS SENT TO

DIAGNOSIS IS AS FOLLOWS:

- 1) KIDNEY, RIGHT, BIOPSY:
- DIABETIC NEPHROPATHY, MILD.
- MILD DIABETIC GLOMERULOPATHY.
- FOCAL SEGMENTAL AND GLOBAL GLOMERULOSCLEROSIS
- FOCAL TUBULAR ATROPHY WITH MILD INTERSTITIAL FIBROSIS.
- MINIMAL CHRONIC INTERSTITIAL INFLAMMATION.
- ARTERIO-AND ARTERIOLOSCLEROSIS, SEVERE.

NOTE: THE ABOVE FINDINGS ARE SUGGESTIVE OF A MILD DIABETIC NEPHROPATHY WHERE PROGRESSIVE VASCULAR SCLEROSIS AND CORTICAL SCARRING PREDOMINATE. NO OTHER SPECIFIC GLOMERULAR LESIONS ARE IDENTIFIED. THE PRESENCE OF FOCAL SEGMENTAL AND GLOBAL GLOMERULOSCLEROSIS WITH AREAS OF COLLAPSE AND ABSENCE OF SIGNIFICANT FOOT PROCESS EFFACEMENT SUGGEST A SECONDARY FORM OF FSGS RELATED TO ADVANCED VASCULAR SCLEROSIS WITH AREAS OF CORTICAL SCARRING IN THIS PATIENT.

[page 3 of 3]
GROSS DESCRIPTION:

THE SPECIMEN WAS SENT TO [REDACTED]

[REDACTED], MICROSCOPIC DESCRIPTION AND ELECTRON MICROSCOPY ARE AS FOLLOWS:

GROSS DESCRIPTION:

RECEIVED IN THE FRESH STATE LABELED WITH THE PATIENT'S NAME AND [REDACTED] A SINGLE FRAGMENT OF PINK-TAN TISSUE MEASURING 1.9 X 0.1 X 0.1 CM. IT IS DIVIDED FOR LIGHT AND ELECTRON MICROSCOPY. 100% SUBMITTED. SUMMARY OF SECTIONS: LM A1 (1).

MICROSCOPIC DESCRIPTION:

TISSUE SUBMITTED FOR LIGHT MICROSCOPY CONSIST OF FRAGMENTS OF RENAL CORTEX CONTAINING UP TO ONE-HUNDRED AND EIGHT (108) GLOMERULI, TWENTY-FIVE (25) OF WHICH ARE GLOBALLY SCLEROSSED AND SCATTERED THROUGHOUT THE CORTEX, NINE (9) SHOW PARTIAL OR SEGMENTAL COLLAPSE WITH CAPSULAR ADHESIONS, SCLEROSIS AND HYALINOSIS (SPECIAL STAINS UTILIZED ARE PAS, PASM AND TRICHROME). THE REMAINING GLOMERULI ARE MODERATELY ENLARGED, SHOWING MINIMAL MESANGIAL EXPANSION WITH MILDLY INCREASED MATRIX. NO SIGNIFICANT PROLIFERATIVE OR INFILTRATIVE PROCESS IS IDENTIFIED IN THESE GLOMERULI. THE PERIPHERAL CAPILLARY WALLS ARE GENERALLY THIN WITH PATENT LUMINA EXCEPT FOR OCCASIONAL GLOMERULI SHOWING SEGMENTAL OR GLOBAL WRINKLING SUGGESTIVE OF ISCHEMIA. SCATTERED FOCI OF TUBULAR ATROPHY ARE ASSOCIATED WITH MILD INTERSTITIAL FIBROSIS, OCCUPYING ABOUT 15% OF THE CORTICAL TISSUE EXAMINED AND ACCOMPANIED BY FOCAL CHRONIC LYMPHOCYTIC INFLAMMATORY INFILTRATE. THE NON-ATROPHIC TUBULES SHOW MILD THICKENING OF BASEMENT MEMBRANES. THE SMALL ARTERIES (UP TO LOBULAR IN SIZE) AND ARTERIOLES EXHIBIT MODERATE MEDIAL HYPERTROPHY AND MARKED FIBROINTIMAL THICKENING LEADING TO CONSIDERABLE NARROWING OF THE LUMINA.

ELECTRON MICROSCOPY:

TISSUE SUBMITTED FOR ELECTRON MICROSCOPY CONSISTS OF FRAGMENTS OF RENAL CORTEX CONTAINING FIVE (5) GLOMERULI. ON EM, THE GLOMERULAR CAPILLARY BASEMENT MEMBRANES ARE MILD TO MODERATELY THICKENED, RANGING FROM 500-650NM, WITH A REGULAR CONTOUR AND TEXTURE. THE FOOT PROCESSES ARE FOCALLY EFFACED, COVERING ABOUT 10-15% OF THE CAPILLARY SURFACE, WHILE ABOUT 20% SHOW DENUDATION FROM THE BASEMENT MEMBRANES. THE OVERLYING VISCERAL EPITHELIAL CELLS SHOW MILD DEGENERATIVE CHANGES AND OCCASIONAL PROTEIN RESORPTION DROPLETS. THE ENDOTHELIAL CELLS ARE UNREMARKABLE. THE MESANGIAL AREAS ARE MILDLY EXPANDED BY INCREASE IN MATRIX AND NORMAL CELLULARITY. NO ELECTRON DENSE DEPOSITS ARE IDENTIFIED WITHIN THE GLOMERULAR CAPILLARY BASEMENT MEMBRANES OR THE MESANGIAL AREAS.

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. MARGIN APPEARS FREE ON ONE REPRESENTATIVE SECTION. [REDACTED]
PERMANENT DIAGNOSIS: SAME [REDACTED]

Source: NCI Genomic Data Commons file e11742b5-c511-4cf6-8f3e-c56b821f9cb3 (TCGA-BP-5185.EFC95B18-6BB6-411A-920E-C6E16BFD06B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).